Somatic mutation profile of tumor specimen 0DF07P from CCDI case PBBRLD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell sarcoma; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.9 years (5,061 days).
Specimen 0DF07P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2c949f8-88d6-4026-83cf-6578a76a96a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF07Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30ec7e8d-2eb8-4d85-81c5-ff330d89055a

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOXL | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 225/509 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779762950, COSV61328846, COSV61330244; called by muse, mutect2, varscan2
- BIRC2 | c.386C>G p.S129C | Missense Mutation (SNP) | VAF 236/596 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs747990760; called by muse, mutect2, varscan2
- CUX2 | c.2587G>A p.A863T | Missense Mutation (SNP) | VAF 22/427 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1239347097; called by muse, mutect2
- MC4R | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 30/744 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as COSV100235980; called by muse, mutect2
- PDE1A | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 237/530 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as rs752732676, COSV59514461; called by muse, mutect2, varscan2
- PRSS27 | c.215C>G p.T72R | Missense Mutation (SNP) | VAF 26/559 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs757297128; called by muse, mutect2
- EPHA2 | c.1729T>G p.S577A | Missense Mutation (SNP) | VAF 220/533 reads (41%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HNRNPA1L2 | c.856T>A p.S286T | Missense Mutation (SNP) | VAF 352/819 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NEURL1B | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 267/576 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OLFML2B | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 201/489 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- OR2C3 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 364/838 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2
- PNLIPRP1 | c.634T>A p.S212T | Missense Mutation (SNP) | VAF 458/1019 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF541 | c.3290C>T p.T1097I | Missense Mutation (SNP) | VAF 29/718 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARPP21 | c.876G>A p.R292= | Silent (SNP) | VAF 315/720 reads (44%) | called by muse, mutect2, varscan2
- NCALD | c.45C>T p.D15= | Silent (SNP) | VAF 313/760 reads (41%) | called by muse, mutect2, varscan2
- CA11 | c.796-25G>T | Intron (SNP) | VAF 273/580 reads (47%) | called by muse, mutect2, varscan2
